Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A67K, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A67K-01A (Primary Tumor).

[page 1 of 4]
MRN
Name
Encounter Number

Gender
Date Of Birth

M

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

C-6CF
ICD-O-3
Adenocarcinoma, NOS 8140/3
Adenocarcinoma, acinar 8140/3
Site: Prostate NOS C61.9
J40 5/9/13

Final

Source of Specimen
PROSTATE GLAND-

FINAL DIAGNOSIS:
PROSTATE GLAND-

ADENOCARCINOMA OF PROSTATE. NO EXTRAPROSTATIC EXTENSION SEEN.

TUMOR SITE: RIGHT AND LEFT, MOSTLY IN PERIPHERAL ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 44 GRAMS. SIZE: 4.5 x 4.5 x 4 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 4 + 3 = 7/10.

NOTE: THE TUMOR IS PREDOMINANTLY GLEASON PATTERN 4 WITH ONLY FEW SCATTERED AREAS OF PATTERN 3 CARCINOMA.

TERTIARY PATTERN: IS NOT PRESENT.

SEVERITY IN EXTENT OF TUMOR: 4 /5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): IS PRESENT, 1.5 CM IN SIZE.

TREATMENT EFFECT ON CARCINOMA: IS NOT IDENTIFIED.

TNM STAGE: pT2c, pNX, pMX.

Prepared for

[page 2 of 4]
LYMPHATIC (SMALL VESSEL) INVASION: IS SEEN, FOCAL.

PERINEURAL INVASION: IS PRESENT, EXTENSIVE.

NO TUMOR SEEN IN SEMINAL VESICLES.

NO TUMOR SEEN AT SPECIMEN MARGINS.

Signature

(Case signed

Case Clinical Information

ADENOCARCINOMA OF THE PROSTATE

Gross Description

Received in formalin labeled with the patient's name "prostate" is a radical prostatectomy specimen which includes a 44 gram prostate gland with attached seminal vesicle and vas deferens. The prostate gland measures 4.5 x 4.5 x 4 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 1.5 x 1 cm. The right vas measures 1.5 x 0.4 x 0.4 cm. The left seminal vesicle measures 1.5 x 1 cm. The left vas measures 1 x 0.4 x 0.4 cm. The inferior prostate is removed from the rest of the specimen and sectioned from anterior to posterior parallel to the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. The specimen is represented as follows: inferior prostate demonstrating apical margin submitted entirely anterior to posterior in A1-A6; bladder resection margin perpendicularly sectioned in A7-A8; complete section of mid gland anterior A9-A10; posterior A11-A12; complete section of upper third of gland, anterior A13-A14; posterior A15-A16; remainder of the posterior gland entirely submitted in A17-A20; right seminal vesicle and vas deferens A21; left seminal vesicle and vas deferens A22.

Physicians

Procedure

A. AA ROUTINE H&E X1 BLOCK.1

Prepared fo

[page 3 of 4]
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
A. AA ROUTINE H&E X1 BLOCK.4
H&E X1
A. AA ROUTINE H&E X1 BLOCK.5
H&E X1
A. AA ROUTINE H&E X1 BLOCK.6
H&E X1
A. AA ROUTINE H&E X1 BLOCK.7
H&E X1
A. AA ROUTINE H&E X1 BLOCK.8
H&E X1
A. AA ROUTINE H&E X1 BLOCK.9
H&E X1
A. AA ROUTINE H&E X1 BLOCK.10
H&E X1
A. AA ROUTINE H&E X1 BLOCK.11
H&E X1 A RECUTS
A. AA ROUTINE H&E X1 BLOCK.12
H&E X1
A. AA ROUTINE H&E X1 BLOCK.13
H&E X1
A. AA ROUTINE H&E X1 BLOCK.14
H&E X1
A. AA ROUTINE H&E X1 BLOCK.15
H&E X1
A. AA ROUTINE H&E X1 BLOCK.16
H&E X1 A RECUTS
A. AA ROUTINE H&E X1 BLOCK.17
H&E X1
A. AA ROUTINE H&E X1 BLOCK.18
H&E X1 A RECUTS
A. AA ROUTINE H&E X1 BLOCK.19
H&E X1 A RECUTS
A. AA ROUTINE H&E X1 BLOCK.20
H&E X1
A. AA ROUTINE H&E X1 BLOCK.21
H&E X1
A. AA ROUTINE H&E X1 BLOCK.22
H&E X1
A. AA ROUTINE H&E X1 BLOCK.23
H&E X1
A. AA ROUTINE H&E X1 BLOCK.24
H&E X1

Prepared for, _____

[page 4 of 4]
Prepared for

Source: NCI Genomic Data Commons file 451a8a24-63f4-4e69-a7e3-da3d3d14f29b (TCGA-J4-A67K.F8FF8077-8922-4CC8-95DD-4AF68CCC7EEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).